Somatic mutation profile of tumor specimen HTMCP-03-06-02364-01A (aliquot HTMCP-03-06-02364-01A-01D-10409) from CGCI case HTMCP-03-06-02364, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 56.1 years (20,485 days).
Specimen HTMCP-03-06-02364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90954ba2-8a7e-4860-982b-2efc7daa4630.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02364-10A (Blood Derived Normal), aliquot HTMCP-03-06-02364-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/873252ee-b400-4cd4-9fd4-ee7f94b3d672

The open-access MAF lists 271 somatic variants for this specimen: 184 protein-altering or splice-affecting, 70 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 70, Nonsense Mutation 15, Intron 9, Splice Region 5, Frame Shift Del 4, 5'Flank 3, 3'UTR 2, 3'Flank 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 59/162 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 107/316 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV55904673; called by muse, mutect2, varscan2
- PTEN | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 63/115 reads (55%) | catalogued as rs786204928, CM992426, COSV64292229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1985T>C p.L662P | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs869025346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV54672374; called by muse, mutect2, varscan2
- AL592490.1 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as rs766069481; called by muse, mutect2, varscan2
- ARHGEF11 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100809780; called by muse, mutect2, varscan2
- C1RL | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56924931; called by muse, mutect2
- CACNA2D4 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.13); catalogued as rs1249922966; called by muse, mutect2, varscan2
- CCSAP | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as rs765708187; called by muse, mutect2, varscan2
- CDK13 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs766263341; called by muse, mutect2, varscan2
- CEP104 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV65517979, COSV65520184; called by muse, varscan2
- CEP57L1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 43/172 reads (25%) | catalogued as rs764837044; called by muse, mutect2, varscan2
- CHST7 | c.985C>G p.R329G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs761217456; called by muse, varscan2
- CPLANE1 | c.7877C>T p.A2626V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762672416; called by muse, mutect2, varscan2
- CTTNBP2 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV50473398; called by muse, mutect2, varscan2
- DCST1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs745591771; called by muse, mutect2, varscan2
- DHX30 | c.1271G>A p.R424Q (on ENST00000445061 / NM_138615.3; = p.R385Q on NM_014966.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs143284982; called by muse, mutect2, varscan2
- DHX9 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV62358263; called by muse, mutect2, varscan2
- DISP3 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV53821686; called by muse, mutect2, varscan2
- DOK6 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101234538, COSV66933467; called by muse, mutect2, varscan2
- ENO1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | catalogued as COSV99318609; called by muse, varscan2
- ENO1 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV52304313; called by muse, mutect2, varscan2
- ERCC8 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54018599; called by muse, mutect2, varscan2
- EVI5 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.05); catalogued as COSV64826493; called by muse, mutect2, varscan2
- FAM135B | c.2632C>T p.L878F | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749205468; called by muse, mutect2, varscan2
- FAM71E2 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1053124643, COSV52772454; called by muse, mutect2, varscan2
- FLNB | c.5116G>A p.D1706N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1316168433; called by muse, mutect2, varscan2
- HECW1 | c.4666C>T p.R1556C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs755187823, COSV67836733; called by muse, mutect2, varscan2
- HIVEP1 | c.6312G>C p.K2104N | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101045348; called by muse, mutect2, varscan2
- IPO7 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV101121847; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.662); catalogued as COSV56440125; called by muse, mutect2, varscan2
- KCNB2 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 53/241 reads (22%) | catalogued as COSV73049818; called by muse, mutect2, varscan2
- LAMC3 | c.4540C>T p.R1514C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs145980204; ClinVar: uncertain significance; called by muse, varscan2
- LRP1 | c.11432C>T p.S3811L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs142687241; called by muse, mutect2, varscan2
- MAEL | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63112295; called by muse, mutect2, varscan2
- MAP1B | c.3560C>T p.S1187F | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57101304; called by muse, mutect2, varscan2
- MAST2 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.926); catalogued as COSV63616498; called by muse, mutect2, varscan2
- MDGA1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs748022262; called by muse, mutect2, varscan2
- MSH2 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CD045345, COSV51875604, COSV51883048; called by muse, mutect2, varscan2
- MUC16 | c.14399C>T p.S4800L | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as rs777222644; called by muse, mutect2, varscan2
- MUC19 | n.19374G>A | Splice Region (SNP) | VAF 9/70 reads (13%) | catalogued as rs947544950; called by muse, mutect2, varscan2
- MYH14 | c.5647G>A p.D1883N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1471106862; called by muse, mutect2, varscan2
- NETO1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.274); catalogued as rs762980649, COSV55007097; called by muse, mutect2, varscan2
- NIBAN1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100836404; called by muse, mutect2, varscan2
- NUP205 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs773304291, COSV53666303, COSV99606665; called by muse, mutect2, varscan2
- NWD2 | c.4501G>A p.E1501K | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.972); catalogued as rs1407601509; called by muse, mutect2, varscan2
- OAS3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs540679155; called by muse, mutect2, varscan2
- PDGFRA | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.624); catalogued as COSV57267589; called by muse, mutect2, varscan2
- PEG3 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV55643022; called by muse, mutect2, varscan2
- PHLPP2 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV100673498; called by muse, mutect2, varscan2
- PKHD1 | c.6901G>A p.V2301M | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs376179014; called by muse, mutect2, varscan2
- PLCB1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs868772684, COSV62047584; called by muse, mutect2, varscan2
- PLCB1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV62036116; called by muse, mutect2, varscan2
- PRR14L | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1239540881, COSV59364231; called by muse, varscan2
- PTPRB | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs184275696, COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- PTPRM | c.3596C>T p.T1199M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs760825169; called by muse, mutect2, varscan2
- PTPRZ1 | c.3016C>G p.L1006V | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs11772668; called by muse, mutect2, varscan2
- QRICH2 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 120/220 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1344710469; called by muse, mutect2, varscan2
- RELCH | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56892195; called by muse, mutect2, varscan2
- ROS1 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63857484; called by muse, mutect2, varscan2
- SCRIB | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1286641675; called by muse, mutect2, varscan2
- SHANK3 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs757887263, COSV53190498; called by muse, mutect2, varscan2
- SPG7 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs373636036; called by muse, mutect2, varscan2
- TP53 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53406994; called by muse, mutect2, varscan2
- TRIM71 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs771002598, COSV67471588; called by muse, mutect2, varscan2
- TRPS1 | c.3461C>T p.S1154L (on ENST00000220888 / NM_001330599.2; = p.S1167L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs973686761, COSV104378180; called by muse, mutect2, varscan2
- TTC3 | c.3850G>C p.E1284Q | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); catalogued as COSV61292598; called by muse, mutect2, varscan2
- TTN | c.67063G>C p.E22355Q (on ENST00000591111; = p.E14931Q on NM_003319.4) | Missense Mutation (SNP) | VAF 73/187 reads (39%) | PolyPhen probably damaging (0.997); catalogued as CX121856; called by muse, mutect2, varscan2
- TTN | c.35170G>C p.E11724Q (on ENST00000591111; = p.E10797Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | PolyPhen benign (0.034); catalogued as COSV60089561; called by muse, mutect2, varscan2
- UBR4 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64385874; called by muse, mutect2, varscan2
- UQCRC2 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99193341; called by muse, mutect2, varscan2
- USP51 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1395558976; called by muse, mutect2, varscan2
- USP6 | c.2827C>G p.R943G | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.528); catalogued as rs552216482, COSV51485421; called by muse, mutect2, varscan2
- VPS16 | c.1725C>A p.F575L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV66792315; called by muse, mutect2, varscan2
- VWCE | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV57112798; called by muse, varscan2
- WNK4 | c.1662C>A p.F554L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV55910486; called by muse, mutect2, varscan2
- ZDHHC11B | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs755126888; called by muse, varscan2
- ZFC3H1 | c.4637C>G p.S1546C | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66432830, COSV66432918; called by muse, mutect2, varscan2
- ZSWIM4 | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs181751370, COSV54323895; called by muse, mutect2, varscan2
- ABCA13 | c.13372G>A p.V4458M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA9 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHI1 | c.3078G>C p.E1026D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMBRA1 | c.3197G>A p.S1066N (on ENST00000458649 / NM_001367468.1; = p.S976N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ASPM | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATP13A4 | c.3422G>C p.R1141T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP8B1 | c.1633C>G p.Q545E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- BLM | c.4121C>G p.S1374C | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- BMPR2 | c.2590C>G p.P864A | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- C16orf96 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C19orf57 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.181); called by muse, varscan2
- CANX | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 53/164 reads (32%) | called by muse, varscan2
- CARMIL1 | c.149C>A p.S50* | Nonsense Mutation (SNP) | VAF 37/145 reads (26%) | called by muse, mutect2, varscan2
- CENPF | c.3875C>G p.S1292C | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CEP112 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD9 | c.4951G>A p.D1651N | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CNKSR1 | c.1999G>C p.E667Q (on ENST00000374253 / NM_001297647.2; = p.E660Q on NM_006314.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- COL11A1 | c.237A>C p.Q79H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A2 | c.3694C>A p.P1232T (on ENST00000341947 / NM_080680.3; = p.P1125T on NM_080679.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPSF1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CPSF2 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CUL9 | c.4780G>C p.E1594Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL9 | c.6464C>A p.S2155Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CUL9 | c.6922-10_6922-8delinsTT | Splice Region (DEL) | VAF 13/68 reads (19%) | called by pindel, varscan2*
- CUL9 | c.7277C>T p.S2426F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DDX3X | c.1865G>C p.S622T (on ENST00000399959; = p.S623T on NM_001356.5) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4A | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DMXL1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- DOCK8 | c.2327G>C p.S776T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2
- DTL | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DZIP1L | c.1527G>T p.R509S | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EFL1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- EGF | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ENO1 | c.576_579delinsAAA p.N194Mfs*34 | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | called by pindel, varscan2*
- EPHA5 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- EPHA7 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.013); called by muse, mutect2
- ERICH3 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ERICH6B | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FCGBP | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- FLT1 | c.774G>C p.L258F | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FOXD4 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.6256G>C p.E2086Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNTL6 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- GLI3 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GSN | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HEPH | c.787C>T p.Q263* (on ENST00000343002; = p.Q317* on NM_138737.5) | Nonsense Mutation (SNP) | VAF 51/129 reads (40%) | called by muse, mutect2, varscan2
- HMCN2 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- KALRN | c.8346C>G p.F2782L (on ENST00000360013 / NM_001024660.4; = p.F1085L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.986); called by muse, varscan2
- KAT2B | c.1253C>G p.S418C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KIAA1109 | c.2696C>G p.S899* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- KLHL4 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LRP1 | c.7359G>A p.M2453I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB6 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- MBD5 | c.2124G>C p.M708I | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MGA | c.5033C>G p.S1678C | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MGA | c.8716G>C p.D2906H (on ENST00000219905 / NM_001164273.1; = p.D2697H on NM_001080541.2) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- MMS22L | c.956G>A p.W319* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- MRPL37 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.797-1G>C p.X266_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- MYO18A | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, varscan2
- NBAS | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NELFCD | c.558+5G>T | Splice Region (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- NRXN1 | c.793C>T p.L265= | Splice Region (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- NRXN3 | c.20C>G p.S7W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.345); called by muse, varscan2
- NUP205 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP214 | c.4964C>T p.S1655L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAF1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PAF1 | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PPP2R3A | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PPP6R3 | c.1582del p.E528Kfs*27 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- PREX2 | c.3801C>A p.F1267L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRR14L | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.117); called by muse, varscan2
- PRX | c.1342C>G p.P448A | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SBF2 | c.2142G>A p.M714I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SBSN | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SDHC | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- SLK | c.2970G>C p.E990D | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMC1B | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SVEP1 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- THADA | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM2 | c.1605G>C p.W535C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNKS2 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TRIM27 | c.1011A>T p.Q337H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRIP12 | c.3744-6C>T | Splice Region (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.26900G>C p.G8967A (on ENST00000591111; = p.G8040A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE4B | c.3746C>G p.S1249C (on ENST00000343090 / NM_001105562.3; = p.S1120C on NM_006048.5) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USPL1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- VIRMA | c.5021C>G p.P1674R | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- WNK1 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YLPM1 | c.5018C>G p.S1673* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- ZBTB10 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ZBTB11 | c.2063_2064del p.F688Yfs*3 | Frame Shift Del (DEL) | VAF 35/250 reads (14%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZDHHC11 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2
- ZFHX3 | c.10965_10980del p.M3655Ifs*34 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8344G>C p.E2782Q | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZMYM2 | c.2470C>G p.Q824E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF180 | c.1418C>A p.S473* | Nonsense Mutation (SNP) | VAF 42/179 reads (23%) | called by muse, mutect2, varscan2
- ZNF208 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF484 | c.236-1G>A p.X79_splice | Splice Site (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- ZNF609 | c.4124C>G p.S1375* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ABCA6 | c.1713C>G p.L571= | Silent (SNP) | VAF 91/352 reads (26%) | called by muse, mutect2, varscan2
- ABCC1 | c.1050C>T p.I350= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- ARPP21 | c.1146G>A p.A382= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1353038689; called by muse, mutect2, varscan2
- ASTN1 | c.2739C>T p.Y913= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1448769436; called by muse, mutect2, varscan2
- ATXN2L | c.3072C>T p.I1024= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs771658704, COSV57366241; called by muse, mutect2, varscan2
- CARD6 | c.1347C>T p.L449= | Silent (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- CCDC183 | c.468G>A p.E156= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- CDH11 | c.1149C>T p.F383= | Silent (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- CDH23 | c.2742C>T p.A914= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs768845897; called by muse, varscan2
- CDHR2 | c.3456C>T p.L1152= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- CFHR5 | c.15C>T p.F5= | Silent (SNP) | VAF 109/276 reads (39%) | catalogued as rs1404375563, COSV56818213; called by muse, mutect2, varscan2
- CNOT1 | c.1719G>A p.L573= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs1567416551; called by muse, mutect2, varscan2
- COBLL1 | c.3225C>T p.F1075= (on ENST00000392717; = p.F1037= on NM_014900.5) | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as rs1217159241; called by muse, mutect2, varscan2
- COL5A1 | c.510C>T p.L170= | Silent (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- CRYBG3 | c.435C>T p.F145= | Silent (SNP) | VAF 109/599 reads (18%) | called by muse, mutect2, varscan2
- DIP2C | c.1611G>C p.V537= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- DRC3 | c.204G>A p.R68= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1055893950; called by muse, mutect2, varscan2
- DSCAML1 | c.5328C>T p.L1776= (on ENST00000321322; = p.L1716= on NM_020693.4) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs761020415; called by muse, mutect2, varscan2
- EIF2AK1 | c.1892G>A p.*631= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV52238881; called by muse, mutect2, varscan2
- F2R | c.303G>T p.L101= | Silent (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- FAM13A | c.1068C>G p.V356= | Silent (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- FNDC1 | c.3114C>T p.A1038= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- GRAMD1B | c.501C>T p.L167= | Silent (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- HECW2 | c.1506G>C p.L502= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV53672310; called by muse, mutect2, varscan2
- HERC1 | c.6078G>A p.E2026= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV101496494; called by muse, mutect2, varscan2
- ICE1 | c.4068C>T p.T1356= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs753769399; called by muse, mutect2, varscan2
- IGSF22 | c.1995C>T p.L665= | Silent (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ITPR2 | c.1437C>G p.L479= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV101189933, COSV67266366; called by muse, mutect2, varscan2
- KCNA5 | c.963C>T p.A321= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs139765997; called by muse, mutect2, varscan2
- KCNT2 | c.420C>T p.F140= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as rs1273443241; called by muse, mutect2, varscan2
- KEAP1 | c.1404C>T p.L468= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- KIF16B | c.786C>T p.T262= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs138579950; called by muse, mutect2, varscan2
- KNTC1 | c.4812C>T p.F1604= | Silent (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- LAMA1 | c.3327C>T p.C1109= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs549501223, COSV67532940; called by muse, mutect2, varscan2
- LATS2 | c.2487C>T p.S829= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1419911271; called by muse, mutect2, varscan2
- MAMDC4 | c.2136C>G p.L712= (on ENST00000445819; = p.L633= on NM_206920.3) | Silent (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- MAP4K5 | c.1044G>C p.L348= | Silent (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- MATR3 | c.2502G>C p.L834= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- MUC12 | c.2286G>C p.L762= (on ENST00000379442; = p.L619= on NM_001164462.1) | Silent (SNP) | VAF 105/250 reads (42%) | called by muse, mutect2, varscan2
- MYF6 | c.156G>A p.A52= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- MYH6 | c.2244C>T p.L748= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs566016734; called by muse, mutect2, varscan2
- MYO1F | c.3144C>G p.A1048= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1299907540; called by muse, mutect2, varscan2
- OAS1 | c.705G>C p.L235= | Silent (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- OR2M5 | c.24C>T p.F8= | Silent (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- PAK5 | c.1212C>T p.L404= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- PCDH9 | c.2352C>T p.I784= | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as rs1401031210, COSV100123452, COSV60594219; called by muse, mutect2, varscan2
- PCDHB10 | c.310C>T p.L104= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs1554283898, COSV53375588; called by muse, mutect2, varscan2
- PCNT | c.8904C>G p.L2968= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV64024536; called by muse, mutect2, varscan2
- PLEKHA6 | c.1986G>A p.L662= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs965786362; called by muse, mutect2, varscan2
- PLXND1 | c.5178G>C p.L1726= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- POLD1 | c.723C>T p.F241= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs764364345, COSV70956464; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRU | c.450C>T p.V150= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60521967; called by muse, mutect2
- QRICH1 | c.1755G>T p.L585= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV62616933; called by muse, mutect2, varscan2
- RNF213 | c.6006G>T p.V2002= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- RNF213 | c.7998C>G p.L2666= | Silent (SNP) | VAF 74/142 reads (52%) | called by muse, mutect2, varscan2
- SI | c.4674C>T p.H1558= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- SMARCC2 | c.3318C>T p.I1106= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- SNX25 | c.1000T>C p.L334= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- SORL1 | c.2943C>G p.L981= | Silent (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- STAT6 | c.1476C>T p.F492= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs749019797, COSV55672816; called by muse, mutect2, varscan2
- THADA | c.1221G>C p.L407= | Silent (SNP) | VAF 60/179 reads (34%) | catalogued as COSV57680225; called by muse, mutect2, varscan2
- TTN | c.47544G>A p.V15848= (on ENST00000591111; = p.V8424= on NM_003319.4) | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV59928319; called by muse, mutect2, varscan2
- UNC13A | c.93C>G p.V31= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- UTRN | c.8808C>G p.L2936= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV62307007; called by muse, mutect2, varscan2
- VEGFC | c.1057C>T p.L353= | Silent (SNP) | VAF 72/249 reads (29%) | catalogued as COSV54592884; called by muse, mutect2, varscan2
- VWDE | c.4257C>A p.P1419= | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- WDR11 | c.1968G>A p.V656= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- ZFHX2 | c.5655G>A p.K1885= | Silent (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- ZNF217 | c.3124C>A p.R1042= | Silent (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- ZNF90 | c.123C>T p.V41= | Silent (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- AC013394.1 | c.-71-3235C>T | Intron (SNP) | VAF 102/278 reads (37%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+1834G>C | Intron (SNP) | VAF 49/229 reads (21%) | called by muse, mutect2, varscan2
- ADGRF5P1 | chr9:62858291 G>A | 3'Flank (SNP) | VAF 121/1150 reads (11%) | called by muse, varscan2
- ARHGAP33 | c.1943-306C>G | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ARID1B | c.*10G>A | 3'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- ATXN2L | c.2686-9C>T | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- CAPN1 | c.338-32G>C | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79621C>T | Intron (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- DNAH14 | c.3051+11383G>A | Intron (SNP) | VAF 45/174 reads (26%) | catalogued as rs1034157853; called by muse, mutect2, varscan2
- FAS | c.*140G>C | 3'UTR (SNP) | VAF 50/152 reads (33%) | catalogued as CM994524; called by muse, mutect2, varscan2
- MIR7162 | chr10:30365039 C>G | 3'Flank (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- MUC19 | n.5811C>T | RNA (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- NF1 | c.1721+60G>A | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- OSCP1 | c.546+3421G>A | Intron (SNP) | VAF 56/238 reads (24%) | called by muse, mutect2, varscan2
- RBM34 | chr1:235161380 C>A | 5'Flank (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- RNU1-1 | chr1:16515548 C>T | 5'Flank (SNP) | VAF 14/224 reads (6%) | catalogued as rs1307568096; called by muse, mutect2
- TUBB8B | chr18:50220 C>T | 5'Flank (SNP) | VAF 99/441 reads (22%) | catalogued as rs374037622; called by muse, mutect2, varscan2
